Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A4Z6, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A4Z6-06A (Metastatic).

Department of Cancer Pathology

Gender: M

Examination result

Clinical diagnosis (suspicion): Skin melanoma of the back with metastasis to the right arm pit.

Material:

1) Material: axillary lymph nodes, right axillary lymph nodes. Method of collection: Total organ resection

Final result:

Metastases of malignant melanoma to the lymph nodes NO II/II. (8010/6

Macroscopic description:

Surgical specimen sized: 6.3 x 2.5 x 2 cm. Fibrous tissue with a brown lesion in the tumour cross section sized 1.8 x 2.5 x 2 cm.

Assistant:

CONTACT YOUR DOCTOR WITH THIS REPORT!

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, axillary C77.3

hw

11/4/12

Diagnostic Discrepancy		X
Dual/Synchronous Primary (Nited)		X

hw 11/4/12

Source: NCI Genomic Data Commons file 2a25d9dc-decd-4558-92d5-4b5e1d84219a (TCGA-D9-A4Z6.27F7E39C-039F-4CDA-99DA-191E6E7FE843.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).